Somatic mutation profile of tumor specimen c6ae57a7-65a0-438e-bae2-97b1c8 (aliquot c6ae57a7-65a0-438e-bae2-97b1c8_D6) from CPTAC case 11CO031, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen c6ae57a7-65a0-438e-bae2-97b1c8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d61b52de-1f42-4ced-9d88-36127ac36923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5d22fc4e-2cfa-4dab-a46b-dd44b9 (Blood Derived Normal), aliquot 5d22fc4e-2cfa-4dab-a46b-dd44b9_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1460724-b3a2-476b-a4e6-c7bda48a5a53

The open-access MAF lists 1,444 somatic variants for this specimen: 958 protein-altering or splice-affecting, 289 silent, 197 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 636, Silent 289, Frame Shift Del 196, Intron 97, Frame Shift Ins 51, Nonsense Mutation 29, 5'UTR 26, 3'UTR 23, RNA 23, Splice Site 18, Splice Region 16, 5'Flank 14.

Variants (750 of 1,444; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARX | c.1187del p.P396Lfs*67 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs1328291159; ClinVar: pathogenic; called by mutect2, pindel
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 70/343 reads (20%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A1 | c.2085dup p.G696Rfs*6 | Frame Shift Ins (INS) | VAF 41/273 reads (15%) | catalogued as rs606231464; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A5 | c.3088G>A p.G1030S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104886210, CM983310, COSV100090203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAMT | c.491del p.G164Afs*14 | Frame Shift Del (DEL) | VAF 64/345 reads (19%) | catalogued as rs749390953, CD041160, CM134498; ClinVar: pathogenic; called by mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AACS | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.438); catalogued as rs1382339205; called by muse, mutect2, varscan2
- AARS2 | c.707A>C p.Q236P | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as rs1561943107; called by muse, mutect2, varscan2
- ABCA4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs193009561, COSV100933396; called by muse, mutect2, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as COSV67016962; called by mutect2, varscan2
- ABCA7 | c.4649del p.P1550Rfs*105 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | catalogued as COSV99565179; called by mutect2, pindel, varscan2
- ABCC2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781337846; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 21/40 reads (53%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC5 | c.2836del p.R946Gfs*15 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as COSV99657198; called by mutect2, pindel, varscan2
- ABCD4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1243757290; called by muse, mutect2, varscan2
- ABRAXAS1 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553936765, COSV58949462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC092143.1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 80/420 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs761851735; called by muse, mutect2, varscan2
- ACTL7B | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV65927391; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs529559129, COSV57440931; called by muse, mutect2, varscan2
- ADAMTS10 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 91/412 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs782569374, COSV54357935; called by muse, mutect2, varscan2
- ADCY5 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1221027778, COSV59196136; called by muse, mutect2, varscan2
- ADGRB1 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs762095707, COSV60097030; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as rs764604854; called by mutect2, pindel, varscan2
- AFTPH | c.931A>G p.S311G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs765244594, COSV99480899; called by muse, mutect2, varscan2
- AHRR | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.278); catalogued as COSV57087142; called by muse, mutect2
- AKNA | c.3692C>T p.A1231V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs151319826; called by muse, mutect2, varscan2
- AL136295.1 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747944183; called by muse, mutect2, varscan2
- ALB | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as rs774958805, COSV99892636; called by muse, mutect2, varscan2
- ALK | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs757811844, COSV66579434; called by muse, mutect2, varscan2
- ANGEL1 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1432218414; called by muse, mutect2, varscan2
- ANKRD20A2P | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.301); catalogued as COSV66464271; called by muse, mutect2, varscan2
- ANKS3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371517379; called by muse, mutect2, varscan2
- ANO1 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1230752062; called by mutect2, varscan2
- APBA1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1473739039; called by muse, mutect2, varscan2
- ARHGAP27 | c.1511A>G p.H504R (on ENST00000428638 / NM_001282290.1; = p.H163R on NM_199282.3) | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs377027866; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV63439114; called by muse, mutect2, varscan2
- ARVCF | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as rs543310231; called by muse, mutect2, varscan2
- ASAP3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1448620878; called by muse, mutect2, varscan2
- ASIC4 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as COSV61731369; called by muse, mutect2, varscan2
- ASPG | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs759467403, COSV101496347; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATAD3B | c.*293G>A | Splice Region (SNP) | VAF 35/179 reads (20%) | catalogued as rs766326080, COSV58020778; called by muse, mutect2, varscan2
- ATG16L1 | c.1004G>A p.R335Q (on ENST00000392017 / NM_030803.7; = p.R316Q on NM_017974.4) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs762578647; called by muse, mutect2, varscan2
- ATP6AP1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs782275544; called by muse, mutect2, varscan2
- ATPSCKMT | c.120_123del p.T41Gfs*13 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs1561031283; called by pindel, varscan2
- ATR | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs886058056, COSV63387513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AWAT1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs776898049, COSV65738622; called by mutect2, varscan2
- BAG4 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs377654190; called by mutect2, varscan2
- BAG4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99782003; called by muse, mutect2, varscan2
- BAG6 | c.2965dup p.Q989Pfs*5 (on ENST00000676571; = p.Q942Pfs*5 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/117 reads (15%) | catalogued as rs778695310; called by mutect2, varscan2
- BCORL1 | c.3208G>T p.G1070C | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV99501182; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 36/204 reads (18%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BHLHA9 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247558305; called by muse, varscan2
- BIVM-ERCC5 | c.1699T>G p.F567V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1361777780; called by muse, mutect2, varscan2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV55587541; called by mutect2, pindel, varscan2
- BRINP1 | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 75/419 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56312135; called by muse, mutect2, varscan2
- BRSK1 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs766247198, COSV58668908; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSX | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159698686; called by muse, mutect2, varscan2
- BTBD11 | c.2474C>T p.T825M (on ENST00000280758 / NM_001018072.2; = p.T362M on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs753438677, COSV99774850; called by muse, mutect2, varscan2
- C15orf62 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs954332698; called by muse, mutect2, varscan2
- C16orf96 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs1293493633; called by muse, mutect2, varscan2
- C1QTNF4 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1215985881, COSV56784126; called by muse, mutect2, varscan2
- C1orf226 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs769021007; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C9orf16 | c.139_141del p.E47del | In Frame Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs759782846; called by pindel, varscan2
- CACNA1D | c.3374G>A p.R1125H (on ENST00000350061 / NM_001128840.3; = p.R1145H on NM_000720.4) | Missense Mutation (SNP) | VAF 70/437 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs570417253; called by muse, mutect2, varscan2
- CACNB3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs901128138, COSV56396951; called by muse, mutect2, varscan2
- CARD10 | c.1823dup p.G609Rfs*109 | Frame Shift Ins (INS) | VAF 23/119 reads (19%) | catalogued as rs1266428698; called by mutect2, pindel, varscan2
- CARMIL1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100278977, COSV99051893; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CCDC127 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs749617804; called by muse, mutect2, varscan2
- CCDC180 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 31/169 reads (18%) | catalogued as COSV100826500; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 40/228 reads (18%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC86 | c.451del p.Q151Sfs*31 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs756540892, COSV57125169; called by mutect2, pindel, varscan2
- CCN4 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 140/734 reads (19%) | catalogued as rs777518726; called by muse, mutect2, varscan2
- CCR1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350782772, COSV56123019; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 29/197 reads (15%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDK19 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs764256188; called by muse, mutect2, varscan2
- CEACAM5 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs371542733; called by muse, mutect2, varscan2
- CERT1 | c.264del p.T89Hfs*85 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | catalogued as rs893362976; called by mutect2, pindel, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 53/314 reads (17%) | catalogued as rs747299117; called by mutect2, varscan2
- CHIA | c.881A>G p.Y294C (on ENST00000343320; = p.Y186C on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1265807849; called by muse, mutect2, varscan2
- CHRNA10 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV51703122; called by muse, mutect2, varscan2
- CLEC4F | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1348136562; called by muse, mutect2, varscan2
- CMYA5 | c.9098C>T p.T3033I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs755487628; called by muse, mutect2, varscan2
- CNGA3 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 85/490 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267734152, COSV99736912; called by muse, mutect2, varscan2
- CNTN6 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63181540; called by muse, mutect2, varscan2
- CNTRL | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs373279905; called by muse, mutect2, varscan2
- COL11A1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs148464130; called by muse, mutect2, varscan2
- COL4A5 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV60355654; called by muse, mutect2, varscan2
- COL5A1 | c.2286G>A p.P762= | Splice Region (SNP) | VAF 46/324 reads (14%) | catalogued as rs766817444, COSV65670906; called by muse, mutect2, varscan2
- COL5A1 | c.4122+1G>A p.X1374_splice | Splice Site (SNP) | VAF 22/149 reads (15%) | catalogued as COSV65672929; called by muse, mutect2, varscan2
- COL6A5 | c.2481del p.K827Nfs*7 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as rs1222064379; called by mutect2, pindel, varscan2
- COL6A6 | c.*5del | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs747090655; called by mutect2, pindel
- CORIN | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764237099; called by muse, mutect2, varscan2
- CPNE1 | c.995C>T p.S332L (on ENST00000352393; = p.S337L on NM_003915.5) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs754279361, COSV58294455; called by muse, mutect2, varscan2
- CPSF1 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs561200816; called by muse, mutect2, varscan2
- CR1 | c.4277G>A p.C1426Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376393868; called by mutect2, varscan2
- CRTAC1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764021235, COSV53997045; called by muse, mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 52/318 reads (16%) | catalogued as rs757082963; called by mutect2, pindel, varscan2
- CSMD1 | c.9469G>A p.G3157R (on ENST00000520002; = p.G3156R on NM_033225.6) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs761247550, COSV100145286; called by muse, mutect2, varscan2
- CTBP1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 110/536 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764862588, COSV52071459; called by muse, mutect2, varscan2
- CTHRC1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.122); catalogued as rs374084026; called by muse, mutect2, varscan2
- CYB5R1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs567416582; called by muse, mutect2, varscan2
- CYP2B6 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757031032, COSV100137283, COSV100137925; called by muse, mutect2, varscan2
- DBNDD1 | c.73G>A p.V25I (on ENST00000002501 / NM_001042610.3; = p.V45I on NM_024043.3) | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.104); catalogued as rs377278023; called by muse, mutect2, varscan2
- DCAF12L1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 115/549 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV64421652; called by muse, mutect2, varscan2
- DCAF4L2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 96/575 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60476386, COSV60476821; called by muse, mutect2, varscan2
- DCP1A | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs781923882; called by muse, mutect2, varscan2
- DCTN6 | c.24-1G>A p.X8_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | catalogued as rs757405420; called by muse, mutect2, varscan2
- DDHD2 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755855117; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs766714372; called by mutect2, varscan2
- DGAT2 | c.1088T>C p.M363T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1405195762; called by muse, mutect2
- DHDDS | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1385971219, COSV99360377; called by muse, mutect2, varscan2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs753024929; called by mutect2, pindel, varscan2
- DMTF1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755806271; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAJB8 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs780929244, COSV100048328; called by muse, mutect2, varscan2
- DNHD1 | c.5587C>T p.R1863C | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs752898762, COSV99600126; called by muse, varscan2
- DNM1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs762553379, COSV57849993; called by muse, varscan2
- DNM1L | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1308058855; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPEP2 | c.1402del p.H468Tfs*51 | Frame Shift Del (DEL) | VAF 37/191 reads (19%) | catalogued as rs1023404475, COSV52055402; called by mutect2, pindel, varscan2
- DPP6 | c.2077C>T p.R693W (on ENST00000377770 / NM_001364500.2; = p.R631W on NM_001936.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs869025385; ClinVar: uncertain significance; called by muse, mutect2
- DRC3 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs367586446; called by muse, mutect2, varscan2
- DXO | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs749081593; called by muse, mutect2, varscan2
- ECPAS | c.4435G>A p.A1479T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV99399561; called by muse, mutect2
- EIF5 | c.58del p.R20Vfs*2 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as COSV53686689; called by mutect2, pindel, varscan2
- ELFN1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.294); catalogued as rs1233837924; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 102/263 reads (39%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- EN1 | c.236del p.P79Rfs*33 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as COSV99726942; called by mutect2, pindel
- EPB41L4A | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs759115856, COSV54868964; called by muse, mutect2, varscan2
- EPB42 | c.1597C>T p.L533F (on ENST00000441366 / NM_001114134.2; = p.L563F on NM_000119.3) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.034); catalogued as rs1004492703, COSV100281988; called by muse, mutect2, varscan2
- EPHB6 | c.849dup p.R284Qfs*41 | Frame Shift Ins (INS) | VAF 39/226 reads (17%) | catalogued as rs145544148; called by mutect2, varscan2
- EPS8L1 | c.1087C>G p.P363A (on ENST00000201647 / NM_133180.3; = p.P236A on NM_017729.3) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99135813; called by muse, mutect2, varscan2
- ERAP2 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1038323058; called by muse, mutect2
- EVPL | c.4846_4848del p.E1616del | In Frame Del (DEL) | VAF 36/185 reads (19%) | catalogued as rs1213930241; called by pindel, varscan2
- EXOC3L1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV52045778; called by muse, mutect2, varscan2
- FAM117A | c.369G>A p.T123= | Splice Region (SNP) | VAF 28/100 reads (28%) | catalogued as rs774309596, COSV53630870; called by muse, mutect2, varscan2
- FAM20A | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.358); catalogued as rs930531234; called by muse, mutect2, varscan2
- FAM216A | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs764074185; called by muse, mutect2, varscan2
- FAM3A | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs376019512; called by muse, mutect2, varscan2
- FBP1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941328; called by muse, mutect2, varscan2
- FBXO31 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs376226613, COSV61149780; called by muse, mutect2, varscan2
- FCGBP | c.5921C>T p.T1974M | Missense Mutation (SNP) | VAF 62/774 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs538992262; called by muse, mutect2
- FEM1A | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs956765564; called by muse, mutect2, varscan2
- FGA | c.2311G>A p.V771I | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs367614797; called by muse, mutect2, varscan2
- FGF22 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1053327160, COSV51260890; called by muse, mutect2, varscan2
- FLNA | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs367948333, COSV61047133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.5058G>T p.E1686D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100145410, COSV100147484, COSV60426905; called by muse, mutect2
- FN1 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100117953; called by muse, varscan2
- FOSL2 | c.355-1G>A p.X119_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV53104136; called by muse, mutect2, varscan2
- FOXG1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 180/900 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57395638; called by muse, mutect2, varscan2
- FPGS | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs372883379; called by muse, mutect2, varscan2
- FPGS | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs1247765964; called by mutect2, varscan2
- FREM1 | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368346957; called by muse, mutect2, varscan2
- FUS | c.1397del p.X466_splice | Splice Site (DEL) | VAF 14/92 reads (15%) | catalogued as rs35711706; called by mutect2, pindel, varscan2
- GALNS | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV51940210; called by muse, mutect2, varscan2
- GATA5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1294824844, COSV53347519; called by muse, mutect2, varscan2
- GFOD2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465127019; called by muse, mutect2, varscan2
- GPATCH8 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs770210247; called by muse, mutect2, varscan2
- GPR50 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as COSV99506450; called by muse, mutect2, varscan2
- GPR62 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as rs1413117244; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs747773579; called by mutect2, varscan2
- GUCY2D | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1245251228, COSV54695712; called by muse, mutect2, varscan2
- GUSB | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251087003, COSV100512597; called by muse, mutect2
- HGD | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs368256121, CM002784; called by muse, mutect2, varscan2
- HMCN2 | c.10594del p.Q3532Sfs*13 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | catalogued as rs1285388324; called by mutect2, pindel, varscan2
- HMGB3 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1246323392; called by muse, mutect2, varscan2
- HOXA2 | c.304_306del p.K102del | In Frame Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs773732762; called by pindel, varscan2
- HOXD3 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); catalogued as COSV50879367; called by muse, mutect2, varscan2
- HROB | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 78/387 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV99809244; called by muse, mutect2, varscan2
- HSPB6 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382943361; called by muse, mutect2, varscan2
- HTR5A | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 104/597 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.231); catalogued as rs1387759460, COSV55281358, COSV55283648; called by muse, mutect2, varscan2
- ICAM4 | c.38del p.L13Wfs*40 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs753968171; called by mutect2, varscan2
- IDH2 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 117/550 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1402492889; called by muse, mutect2, varscan2
- IGSF1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1215064968, COSV63836099; called by muse, mutect2, varscan2
- IL36G | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99381186; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs776023104; called by pindel, varscan2
- INTS4 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs748648093; called by muse, mutect2, varscan2
- IP6K1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1359739943, COSV58665075; called by muse, mutect2, varscan2
- IPO5 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55154237; called by muse, mutect2
- IQCF2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759436786, COSV60761963; called by muse, mutect2, varscan2
- IQSEC3 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs374686235; called by muse, mutect2, varscan2
- IRS4 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1381444291, COSV64533402; called by muse, mutect2, varscan2
- KANSL1 | c.2981C>T p.P994L (on ENST00000574590 / NM_001193465.2; = p.P995L on NM_015443.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761819132; ClinVar: likely benign; called by muse, mutect2
- KANSL1L | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs969909279; called by muse, mutect2, varscan2
- KCND3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as rs760055752, COSV56175627; called by muse, varscan2
- KCNH3 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs375049572; called by muse, mutect2, varscan2
- KCNH7 | c.2245dup p.A749Gfs*3 | Frame Shift Ins (INS) | VAF 26/203 reads (13%) | catalogued as rs757276514; called by mutect2, pindel, varscan2
- KCTD10 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1348342130, COSV57327774; called by muse, mutect2, varscan2
- KDR | c.2063G>A p.C688Y | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773077; called by muse, mutect2, varscan2
- KDR | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761405036, COSV55777162; called by muse, mutect2, varscan2
- KIF21B | c.3135G>A p.G1045= | Splice Region (SNP) | VAF 58/298 reads (19%) | catalogued as rs763331252; called by muse, mutect2, varscan2
- KLHDC1 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs774957293; called by mutect2, varscan2
- KLHDC7A | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV68770218; called by muse, mutect2, varscan2
- KMT2B | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV52892023; called by muse, mutect2, varscan2
- KPRP | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 171/389 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs769955421; called by muse, mutect2, varscan2
- KREMEN1 | c.113C>T p.A38V (on ENST00000407188; = p.A40V on NM_032045.5) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs749531697; called by muse, mutect2, varscan2
- KRT33B | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV52440697; called by muse, mutect2, varscan2
- KRTAP13-3 | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs758599717, COSV61879762; called by muse, mutect2, varscan2
- KSR1 | c.565C>T p.R189W (on ENST00000644974 / NM_001367810.1; = p.R52W on NM_014238.2) | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759278857, COSV52030256; called by muse, mutect2, varscan2
- LGALS13 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1303608067, COSV99695050; called by muse, mutect2, varscan2
- LGALS14 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs199912882, COSV62373040; called by muse, mutect2, varscan2
- LGALS3BP | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53165831; called by muse, mutect2, varscan2
- LHX9 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs765975854, COSV100435776, COSV61326746; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 30/167 reads (18%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMOD3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs370401036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP12 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs777436090, COSV99407769; called by muse, mutect2, varscan2
- LRRC7 | c.2280G>A p.W760* (on ENST00000651989 / NM_001370785.2; = p.W727* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99066444; called by muse, mutect2, varscan2
- LRRK1 | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs370451042, COSV99437907; called by muse, mutect2, varscan2
- LRRN2 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100913028; called by muse, mutect2, varscan2
- MAGEC1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1158467484, COSV99595406, COSV99595609; called by muse, mutect2, varscan2
- MAP4K3 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755676925, COSV55712403; called by muse, mutect2, varscan2
- MARCO | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.044); catalogued as COSV100503203; called by muse, mutect2, varscan2
- MAST3 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs867663456; called by muse, mutect2, varscan2
- MBD2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160707623, COSV56500562; called by muse, mutect2, varscan2
- MBD2 | c.471del p.G158Dfs*7 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs755716804, COSV56502366; called by mutect2, varscan2
- MBNL2 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs537929130; called by muse, mutect2, varscan2
- MCF2 | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1398731059; called by muse, mutect2, varscan2
- MDFIC | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as rs202170562; called by muse, mutect2, varscan2
- MDGA2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs947844781, COSV101229674; called by muse, mutect2, varscan2
- MET | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs45602940, COSV59260108; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- MGAM | c.4583C>T p.T1528M | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.322); catalogued as rs370790394; called by muse, mutect2, varscan2
- MIB2 | c.282-6C>T | Splice Region (SNP) | VAF 21/98 reads (21%) | catalogued as rs1296695944; called by muse, mutect2, varscan2
- MICAL3 | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52894873; called by muse, mutect2
- MICAL3 | c.615C>A p.H205Q | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1301758693; called by muse, mutect2
- MINDY3 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99510405; called by muse, mutect2, varscan2
- MIPEP | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546719717, COSV66301531; called by muse, mutect2, varscan2
- MN1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1191573479; called by muse, mutect2, varscan2
- MORC4 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV55239261; called by muse, mutect2, varscan2
- MRC2 | c.522G>A p.E174= | Splice Region (SNP) | VAF 20/98 reads (20%) | catalogued as rs1225324641; called by muse, mutect2, varscan2
- MRC2 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57636284; called by muse, mutect2, varscan2
- MRTFA | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1295279056, COSV62932348; called by muse, mutect2, varscan2
- MTG1 | c.986dup p.A330Gfs*2 | Frame Shift Ins (INS) | VAF 20/107 reads (19%) | catalogued as rs770677100; called by mutect2, pindel, varscan2
- MYBBP1A | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs565454228, COSV54594520; called by muse, mutect2, varscan2
- MYH10 | c.4577del p.N1526Tfs*12 | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | catalogued as COSV52597559; called by mutect2, pindel, varscan2
- MYH10 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs752480302; called by muse, mutect2
- MYL5 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1217610675; called by mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as rs748007891; called by mutect2, pindel, varscan2
- MYO18B | c.5893G>A p.V1965I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs1020839140; called by muse, mutect2, varscan2
- MYO1F | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as rs759707124, COSV57793206; called by muse, mutect2, varscan2
- MYO6 | c.3544C>T p.R1182C (on ENST00000369981; = p.R1172C on NM_004999.4) | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752568854; called by muse, mutect2, varscan2
- MYO9A | c.7196C>T p.A2399V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.1); catalogued as rs760675165, COSV100612564; called by muse, mutect2, varscan2
- MYOCD | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs372478735, COSV58503063; called by muse, mutect2, varscan2
- NAGA | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1569458798, COSV67170180; called by muse, mutect2, varscan2
- NAV2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs765091913, COSV62330786; called by muse, varscan2
- NAV2 | c.2458G>A p.A820T (on ENST00000396087 / NM_001244963.2; = p.A797T on NM_145117.5) | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs140354139, COSV62320806; called by muse, mutect2, varscan2
- NCAN | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs775437640, COSV53048774; called by muse, mutect2, varscan2
- NDC1 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs759180095; called by muse, mutect2, varscan2
- NF1 | c.3653A>G p.Q1218R | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs876659541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.808G>A p.A270T (on ENST00000339876 / NM_001378329.1; = p.A281T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs371635013, COSV58370618; called by muse, mutect2, varscan2
- NIBAN3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777044790; called by muse, mutect2, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NIPBL | c.3923C>T p.A1308V | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs1170839204, COSV56950810; called by muse, mutect2, varscan2
- NMUR2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); catalogued as rs1467639009, COSV54917384; called by muse, mutect2, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 41/266 reads (15%) | catalogued as rs1402340327; called by mutect2, pindel, varscan2
- NOL6 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466956849, COSV99954489; called by muse, mutect2, varscan2
- NRXN1 | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.205); catalogued as COSV58445141; called by muse, mutect2, varscan2
- NSUN3 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763714773; called by muse, mutect2, varscan2
- NUDT11 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV101047005; called by muse, mutect2, varscan2
- NYNRIN | c.4871C>T p.P1624L | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762806768; called by muse, mutect2, varscan2
- OR10H5 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs372682146; called by muse, mutect2, varscan2
- OR6P1 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs745388212; called by muse, mutect2, varscan2
- OTOA | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs759414633; called by muse, mutect2, varscan2
- OTOP1 | c.829T>C p.Y277H | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908906640; called by muse, mutect2, varscan2
- PANK4 | c.72dup p.D25Rfs*50 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | catalogued as rs768596064; called by pindel, varscan2
- PARD6G | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.198); catalogued as COSV62062027; called by muse, mutect2, varscan2
- PARG | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs1416833904, COSV67858307; called by muse, mutect2, varscan2
- PARP10 | c.2293C>A p.R765S | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100477740; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 70/364 reads (19%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH10 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52099108, COSV99993103; called by muse, varscan2
- PCDHGA8 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99540220; called by muse, mutect2, varscan2
- PDZD4 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51245402; called by muse, mutect2, varscan2
- PHF21A | c.613-6del | Splice Region (DEL) | VAF 12/59 reads (20%) | catalogued as rs772754445; called by mutect2, pindel, varscan2
- PHRF1 | c.2108G>A p.S703N (on ENST00000264555 / NM_001286581.2; = p.S702N on NM_020901.4) | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.105); catalogued as rs760103054; called by muse, mutect2, varscan2
- PHTF2 | c.1709del p.L570Cfs*4 (on ENST00000248550 / NM_001366089.1; = p.L532Cfs*4 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs775426168; called by mutect2, varscan2
- PIP4K2A | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs1478855220; called by muse, mutect2, varscan2
- PIP5KL1 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1165463810; called by muse, mutect2, varscan2
- PKD1 | c.8549C>T p.S2850L | Missense Mutation (SNP) | VAF 164/806 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779813643; called by muse, mutect2, varscan2
- PLEKHG6 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 92/458 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs145462189; called by muse, mutect2, varscan2
- PLXNA3 | c.5237C>T p.A1746V | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755812; called by muse, mutect2, varscan2
- PLXNB3 | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1048660836; called by muse, mutect2, varscan2
- PML | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.754); catalogued as rs1438297871, COSV51441538; called by muse, mutect2, varscan2
- POMGNT1 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 41/240 reads (17%) | PolyPhen possibly damaging (0.781); catalogued as rs1164161791; called by muse, mutect2, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 54/258 reads (21%) | catalogued as rs775721804; called by mutect2, varscan2
- PPP1R10 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.151); catalogued as rs200122275, COSV100919815; called by mutect2, varscan2
- PPP1R13L | c.1318del p.Q440Sfs*10 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs1555782094; called by mutect2, pindel, varscan2
- PPP1R42 | c.552+3A>G | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV61207905; called by muse, mutect2
- PPP2R2C | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs367696094; called by muse, mutect2, varscan2
- PRF1 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as rs577367079; called by muse, mutect2, varscan2
- PRICKLE3 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as rs1557099987, COSV100889902; called by muse, mutect2, varscan2
- PRKG1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100907078; called by muse, mutect2, varscan2
- PRR3 | c.90_92del p.E30del | In Frame Del (DEL) | VAF 29/136 reads (21%) | catalogued as rs751678157; called by pindel, varscan2
- PRSS21 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774890310, COSV50052627; called by muse, mutect2, varscan2
- PSMC5 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs780412308; called by muse, mutect2, varscan2
- PSMD9 | c.594del p.K198Nfs*46 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs750466620; called by mutect2, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 51/274 reads (19%) | catalogued as rs763413121; called by mutect2, pindel, varscan2
- PTGFRN | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.301); catalogued as rs149030409, COSV67798014; called by muse, mutect2, varscan2
- PTGS2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776721278, COSV66568331; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPRZ1 | c.3248C>T p.A1083V | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs778883937, COSV66431774; called by muse, mutect2, varscan2
- R3HDM4 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs923554262; called by muse, varscan2
- RABL6 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs758669107; called by muse, mutect2, varscan2
- RANBP17 | c.1884del p.K628Nfs*3 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as COSV101206115; called by mutect2, pindel, varscan2
- RAPGEF3 | c.292C>T p.L98F (on ENST00000389212; = p.L56F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV50203446; called by muse, mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 32/234 reads (14%) | catalogued as rs771909008; called by mutect2, varscan2
- RASD2 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1442019893, COSV53352044; called by muse, mutect2, varscan2
- RDX | c.1412dup p.P472Sfs*16 | Frame Shift Ins (INS) | VAF 19/96 reads (20%) | catalogued as rs780998172; called by mutect2, varscan2
- RESP18 | c.209del p.G70Afs*14 | Frame Shift Del (DEL) | VAF 34/197 reads (17%) | catalogued as COSV61114468; called by mutect2, pindel, varscan2
- RETREG3 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs145552422; called by muse, mutect2, varscan2
- RFPL1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.217); catalogued as rs1461422777; called by muse, mutect2, varscan2
- RFX7 | c.1229G>A p.S410N (on ENST00000559447 / NM_001368074.1; = p.S507N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs948787460; called by muse, mutect2, varscan2
- RGS12 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275683331; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIC8A | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs780174900; called by muse, mutect2, varscan2
- RIMS2 | c.4531G>A p.E1511K (on ENST00000666250 / NM_001348490.2; = p.E1082K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs549202122, COSV51651550; called by muse, mutect2, varscan2
- RIPOR1 | c.1772C>A p.P591H (on ENST00000379312 / NM_001193522.2; = p.P587H on NM_024519.4) | Missense Mutation (SNP) | VAF 67/377 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV50217370; called by muse, mutect2, varscan2
- RNF222 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs1219281529; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL7L1 | c.403del p.Q135Rfs*3 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs1188486343; called by mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- S1PR2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs755629087; called by muse, mutect2, varscan2
- SAFB | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52650046; called by muse, mutect2, varscan2
- SCNM1 | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99766241; called by muse, mutect2, varscan2
- SCYL1 | c.1509_1510del p.A504Pfs*15 | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | catalogued as rs864309665; called by pindel, varscan2
- SEC16B | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs1380120878; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3A | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs138002949; called by muse, mutect2, varscan2
- SEMA4F | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 92/405 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs765697118; called by muse, mutect2, varscan2
- SERPINA3 | c.570del p.I192Sfs*4 | Frame Shift Del (DEL) | VAF 42/183 reads (23%) | catalogued as rs35203201; called by mutect2, pindel, varscan2
- SERPINB9 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs202159163, COSV66233937; called by muse, varscan2
- SETD1B | c.4916G>A p.R1639Q | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs1053033775; called by muse, mutect2, varscan2
- SETDB2 | c.18C>T p.G6= | Splice Region (SNP) | VAF 9/37 reads (24%) | catalogued as rs770637591, COSV51643593; called by muse, mutect2, varscan2
- SFI1 | c.2899G>A p.A967T (on ENST00000400288 / NM_001007467.3; = p.A936T on NM_014775.4) | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs1467451871; called by muse, mutect2, varscan2
- SFMBT2 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750153697, COSV100738479; called by muse, mutect2, varscan2
- SHANK2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); catalogued as rs1031969100; called by muse, mutect2, varscan2
- SHC1 | c.1627C>T p.R543W (on ENST00000368445 / NM_183001.5; = p.R434W on NM_003029.5) | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221783605, COSV63534987; called by muse, mutect2, varscan2
- SI | c.5056C>A p.R1686S | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52264367; called by muse, mutect2, varscan2
- SKAP1 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as rs753812443; called by muse, mutect2, varscan2
- SLC16A6 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs377560800; called by muse, mutect2, varscan2
- SLC23A2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331637883; called by muse, mutect2, varscan2
- SLC26A4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM040111; called by muse, mutect2, varscan2
- SLC26A6 | c.2114T>C p.M705T | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1170721258; called by muse, mutect2, varscan2
- SLC4A11 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 99/466 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs201560423; called by mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC8A2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52641980; called by muse, mutect2, varscan2
- SLC8A2 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs201707453, COSV99370290; called by mutect2, varscan2
- SLC8A3 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1449800335; called by muse, mutect2, varscan2
- SLC9A3 | c.1682C>A p.S561Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs371187218; called by muse, mutect2, varscan2
- SLITRK4 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1556427444, COSV62024355, COSV62026512; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs766085867, COSV100391091; called by mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SNTB1 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs766007543, COSV67324799; called by muse, mutect2, varscan2
- SNX20 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs562563894, COSV56057635; called by muse, mutect2, varscan2
- SPATA31E1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57794909; called by muse, mutect2, varscan2
- SPEN | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs975826717, COSV65358866; called by muse, mutect2, varscan2
- SPTLC2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs773212643, COSV53643888; called by muse, mutect2, varscan2
- SPZ1 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs768155239; called by muse, mutect2, varscan2
- SQLE | c.254dup p.E86* | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | catalogued as rs760774524; called by mutect2, varscan2
- SREBF1 | c.3224C>T p.A1075V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs1434197197; called by muse, mutect2, varscan2
- SSC5D | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV67477175; called by muse, mutect2, varscan2
- SSC5D | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs780185928; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | PolyPhen possibly damaging (0.712); catalogued as rs763231763; called by muse, mutect2
- STAM | c.1210-2A>G p.X404_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as rs1218313507; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT2 | c.1467dup p.K490Qfs*41 | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | catalogued as rs763294380; called by mutect2, varscan2
- STIL | c.3363del p.K1121Nfs*3 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as COSV99680901; called by mutect2, pindel, varscan2
- SULF2 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs143301039; called by muse, mutect2, varscan2
- SULT1C2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374614997; called by muse, mutect2, varscan2
- SYT1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54041266; called by muse, mutect2, varscan2
- SYTL3 | c.1813A>G p.M605V (on ENST00000611299 / NM_001242394.1; = p.M537V on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs773291858; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TAGAP | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs1163344179, COSV57851040; called by muse, mutect2, varscan2
- TAS2R50 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760495089, COSV101114352; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D30 | c.1141C>T p.R381W (on ENST00000542120; = p.R218W on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs970164244, COSV57479848; called by muse, mutect2, varscan2
- TCAF2C | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs1393785522; called by mutect2, varscan2
- TCHH | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV64276678; called by muse, mutect2, varscan2
- TCP10L | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100291896; called by muse, mutect2, varscan2
- TECTA | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as rs200340759, COSV50725210; called by muse, mutect2, varscan2
- TGM5 | c.907G>A p.D303N (on ENST00000220420 / NM_201631.4; = p.D221N on NM_004245.4) | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs369401093; called by muse, mutect2, varscan2
- THADA | c.3662C>T p.T1221M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs763566405, COSV100369159; called by muse, mutect2, varscan2
- THEMIS | c.1661del p.P554Hfs*10 | Frame Shift Del (DEL) | VAF 61/396 reads (15%) | catalogued as COSV64073417; called by mutect2, pindel, varscan2
- TIE1 | c.1341dup p.V448Rfs*55 | Frame Shift Ins (INS) | VAF 19/115 reads (17%) | catalogued as rs758071080; called by mutect2, pindel, varscan2
- TINAG | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779047105; called by muse, mutect2, varscan2
- TKTL1 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV54212236; called by muse, mutect2, varscan2
- TLR9 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1224643512; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEM132E | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1424057357; called by muse, mutect2
- TMEM268 | c.51dup p.S18Lfs*32 | Frame Shift Ins (INS) | VAF 14/74 reads (19%) | catalogued as rs1292856103; called by mutect2, pindel, varscan2
- TMEM63C | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV53601475; called by muse, mutect2, varscan2
- TNFSF9 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs766150013; called by muse, mutect2, varscan2
- TNS2 | c.1120C>T p.R374W (on ENST00000314250 / NM_170754.4; = p.R384W on NM_015319.2) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs149747461; called by muse, mutect2, varscan2
- TNXB | c.11110G>A p.V3704M (on ENST00000647633; = p.V3457M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199623625; called by muse, mutect2, varscan2
- TNXB | c.9267del p.N3090Tfs*8 (on ENST00000647633; = p.N2843Tfs*8 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 83/382 reads (22%) | catalogued as COSV64489286; called by mutect2, pindel, varscan2
- TONSL | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423245887; called by muse, mutect2, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TPK1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147602742; called by muse, mutect2, varscan2
- TPTE2 | c.946G>A p.V316I (on ENST00000400230 / NM_199254.2; = p.V239I on NM_130785.3) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs374764694, COSV55015930; called by muse, mutect2, varscan2
- TRIM68 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 101/535 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs750120044; called by muse, mutect2, varscan2
- TRUB2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1394617394; called by muse, mutect2, varscan2
- TSPEAR | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329340778, COSV59981997; called by muse, mutect2, varscan2
- TTBK1 | c.3101C>A p.P1034H | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.319); catalogued as COSV52489587; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL8 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as rs1295895844; called by muse, mutect2, varscan2
- TUBGCP4 | c.1504C>T p.R502C (on ENST00000260383 / NM_001286414.3; = p.R501C on NM_014444.5) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV53019142; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs760251146; called by mutect2, varscan2
- TYMP | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1253283946; called by muse, mutect2, varscan2
- UBR1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1190528436; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs763652408; called by mutect2, varscan2
- UGGT1 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1218499495; called by muse, mutect2, varscan2
- ULK4 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs202044928; called by muse, mutect2, varscan2
- UNC119 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1333991796; called by muse, mutect2
- UNKL | c.1915_1917del p.E639del (on ENST00000389221 / NM_001372107.1; = p.E135del on NM_001276414.2) | In Frame Del (DEL) | VAF 63/357 reads (18%) | catalogued as rs772955236; called by pindel, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | catalogued as rs767420916; called by mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 39/161 reads (24%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- UTRN | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761620103, COSV62331139; called by muse, mutect2, varscan2
- VCAN | c.8560G>A p.V2854I | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747328962, COSV54116544; called by muse, mutect2, varscan2
- VGLL2 | c.920G>A p.R307H (on ENST00000326274 / NM_182645.3; = p.R133H on NM_153453.1) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100409963; called by muse, mutect2, varscan2
- VPS51 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV54207348; called by muse, varscan2
- VPS52 | c.2170T>C p.*724Rext*55 | Nonstop Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs766352589; called by muse, mutect2, varscan2
- VRK2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs755287817; called by muse, mutect2, varscan2
- VWA5B1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs920145583; called by muse, mutect2, varscan2
- VWA8 | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs752758480, COSV64998569; called by muse, mutect2, varscan2
- WDR62 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1170829156; called by mutect2, varscan2
- WDR72 | c.2332dup p.M778Nfs*4 | Frame Shift Ins (INS) | VAF 48/278 reads (17%) | catalogued as rs764406738; called by mutect2, varscan2
- WDR93 | c.1574del p.C525Lfs*223 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as COSV51531523; called by mutect2, pindel, varscan2
- WFDC6 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100323318; called by muse, mutect2
- WNT16 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.253); catalogued as rs867332829; called by muse, mutect2, varscan2
- WNT7A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 88/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456656577, COSV53197111, COSV99541812; called by muse, mutect2, varscan2
- XKR6 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.121); catalogued as rs1343118842; called by muse, mutect2, varscan2
- XRCC4 | c.643del p.T215Lfs*7 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as COSV56534703; called by mutect2, pindel, varscan2
- YLPM1 | c.761dup p.G255Wfs*3 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | catalogued as rs760065689; called by mutect2, varscan2
- ZBTB7C | c.902del p.P301Hfs*38 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as COSV59691239; called by mutect2, pindel, varscan2
- ZCCHC12 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV100038379; called by mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- ZNF497 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs1451213630; called by muse, mutect2, varscan2
- ZNF516 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 96/418 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs1252826711, COSV71586698; called by mutect2, varscan2
- ZNF517 | c.390del p.H131Tfs*95 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs746799858; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF646 | c.1643del p.P548Rfs*48 | Frame Shift Del (DEL) | VAF 50/224 reads (22%) | catalogued as rs768613284; called by mutect2, varscan2
- ZNF683 | c.438del p.C147Afs*91 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | catalogued as COSV100853722; called by mutect2, pindel, varscan2
- ZNF687 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1008363289; called by muse, mutect2, varscan2
- ZNF689 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs774313641, COSV54908890; called by muse, mutect2, varscan2
- ZNF7 | c.692del p.K231Sfs*59 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs1398210459; called by mutect2, pindel, varscan2
- ZNF710 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.972); catalogued as rs765120913; called by muse, varscan2
- ZNF852 | c.372dup p.S125Ifs*7 | Frame Shift Ins (INS) | VAF 26/157 reads (17%) | catalogued as rs1212957945; called by mutect2, pindel, varscan2
- ZNF880 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as rs1304757578; called by muse, mutect2, varscan2
- A2M | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABCA8 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ABCB6 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- AC011840.1 | n.995G>T | Splice Region (SNP) | VAF 55/278 reads (20%) | called by mutect2, varscan2
- ACKR4 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTR3 | c.849dup p.H284Sfs*6 | Frame Shift Ins (INS) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ADAMTS16 | c.2015A>G p.Q672R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS17 | c.1591del p.E531Sfs*3 | Frame Shift Del (DEL) | VAF 56/290 reads (19%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 122/500 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by mutect2, varscan2
- ADIPOR1 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | called by muse, mutect2, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, varscan2
- AKAP13 | c.3554C>A p.P1185H | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- AL136295.3 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated, low confidence (0.25); called by muse, mutect2, varscan2
- ALPK1 | c.1534T>C p.C512R | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER1 | c.35del p.K12Rfs*41 | Frame Shift Del (DEL) | VAF 55/264 reads (21%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.3907G>T p.G1303C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANHX | c.393del p.S132Pfs*7 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.1361T>G p.L454R | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD36C | c.4164del p.D1389Tfs*3 | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | called by mutect2, varscan2
- ANLN | c.2695del p.T899Hfs*16 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- AP1G2 | c.2257-1G>T p.X753_splice | Splice Site (SNP) | VAF 43/206 reads (21%) | called by muse, mutect2, varscan2
- AP5B1 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.889); called by muse, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 52/270 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP23 | c.4436C>T p.P1479L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF12 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ARHGEF17 | c.1030T>C p.W344R | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF35 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by mutect2, varscan2
- ARID1A | c.1793_1794insA p.P599Sfs*24 | Frame Shift Ins (INS) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- ASB6 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASB7 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- ATP10A | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP11C | c.2225del p.A743Hfs*10 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.1772T>C p.M591T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP1A3 | c.1310A>G p.K437R (on ENST00000545399 / NM_001256214.2; = p.K424R on NM_152296.5) | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ATP2B3 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 57/266 reads (21%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- ATXN1L | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GAT2 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT7 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- B4GALNT4 | c.295dup p.A99Gfs*29 | Frame Shift Ins (INS) | VAF 20/144 reads (14%) | called by mutect2, varscan2
- BACE1 | c.107del p.G36Afs*32 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, varscan2
- BEAN1 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BICRAL | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- BNIP5 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BTBD1 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BTBD18 | c.662del p.N221Tfs*63 | Frame Shift Del (DEL) | VAF 48/223 reads (22%) | called by mutect2, pindel, varscan2
- C11orf45 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- C16orf89 | c.1112del p.L371* | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, varscan2
- C1QTNF6 | c.51+1G>A p.X17_splice | Splice Site (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- C1orf174 | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C3AR1 | c.549T>A p.D183E | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C5 | c.3682del p.W1228Gfs*21 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- CABIN1 | c.5472del p.A1825Pfs*81 | Frame Shift Del (DEL) | VAF 43/268 reads (16%) | called by mutect2, pindel, varscan2
- CABP5 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNA1B | c.1422del p.F474Lfs*6 | Frame Shift Del (DEL) | VAF 104/585 reads (18%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.1747A>C p.S583R (on ENST00000356253 / NM_001366867.1; = p.S564R on NM_000722.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CACNA2D2 | c.2313dup p.N772Qfs*5 (on ENST00000479441 / NM_001174051.3; = p.N765Qfs*5 on NM_006030.4) | Frame Shift Ins (INS) | VAF 44/233 reads (19%) | called by mutect2, pindel, varscan2
- CADM2 | c.711del p.P238Hfs*7 (on ENST00000407528 / NM_001167674.2; = p.P240Hfs*7 on NM_153184.4) | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CAMLG | c.46del p.V16Sfs*23 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.297del p.N100Tfs*28 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- CATSPERD | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- CCDC168 | c.7951G>A p.G2651S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCN2 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CCR2 | c.742A>G p.I248V | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CD276 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CD79A | c.224del p.T75Sfs*17 | Frame Shift Del (DEL) | VAF 110/688 reads (16%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 74/201 reads (37%) | called by mutect2, varscan2
- CDSN | c.1057A>C p.S353R | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CEACAM18 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CELSR3 | c.6466del p.A2156Pfs*38 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- CEP170 | c.1346C>A p.P449Q | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CERS2 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP47 | c.4182del p.F1394Lfs*44 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- CFAP47 | c.7592G>A p.G2531D | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP65 | c.3833del p.G1278Afs*6 | Frame Shift Del (DEL) | VAF 48/223 reads (22%) | called by mutect2, pindel, varscan2
- CHD7 | c.7635dup p.E2546* | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.960del p.A321Qfs*38 (on ENST00000372045; = p.A327Qfs*38 on NM_145234.4) | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- CHRM3 | c.974A>C p.E325A | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHST7 | c.977del p.G326Afs*16 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- CNDP1 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT8 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNPY4 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG7 | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A2 | c.1597-1G>T p.X533_splice | Splice Site (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- COL6A6 | c.4905del p.G1636Efs*55 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- COL7A1 | c.8110-8C>T | Splice Region (SNP) | VAF 43/181 reads (24%) | called by muse, mutect2, varscan2
- COQ2 | c.1184del p.L395* | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7084G>A p.V2362I (on ENST00000297405 / NM_001363185.1; = p.V2258I on NM_052900.3) | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAGLB | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DALRD3 | c.785G>A p.S262N (on ENST00000341949 / NM_001009996.3; = p.S95N on NM_018114.5) | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCSTAMP | c.429del p.K143Nfs*16 | Frame Shift Del (DEL) | VAF 41/239 reads (17%) | called by mutect2, pindel, varscan2
- DENND2D | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DHRS3 | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 89/480 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DICER1 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DIDO1 | c.3797del p.P1266Lfs*8 | Frame Shift Del (DEL) | VAF 52/244 reads (21%) | called by mutect2, pindel, varscan2
- DLEC1 | c.5008A>G p.T1670A | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DNAH5 | c.1294del p.I432Yfs*7 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | called by mutect2, pindel, varscan2
- DNAI3 | c.225del p.F75Lfs*55 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel, varscan2
- DNAJB8 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DNM2 | c.554A>T p.D185V | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNTT | c.754T>G p.F252V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DPH5 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSEL | c.2905del p.R969Efs*16 | Frame Shift Del (DEL) | VAF 29/175 reads (17%) | called by mutect2, pindel, varscan2
- DST | c.20865G>T p.Q6955H (on ENST00000361203 / NM_001374722.1; = p.Q4652H on NM_015548.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.10889A>G p.Q3630R | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DTWD1 | c.857A>G p.Q286R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF3D | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- EIF4H | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELK1 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML2 | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ENTR1 | c.1012G>A p.A338T (on ENST00000357365 / NM_001039707.2; = p.A315T on NM_006643.4) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPG5 | c.4397G>T p.W1466L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPPK1 | c.6302G>T p.R2101M | Missense Mutation (SNP) | VAF 93/401 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ERICH3 | c.2210C>G p.A737G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ERO1B | c.189del p.K63Nfs*15 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- ETS1 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EVPL | c.1103del p.P368Lfs*73 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- EXPH5 | c.3673del p.T1225Hfs*20 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- FAM184B | c.960del p.K320Nfs*13 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- FAM193A | c.2017dup p.L673Pfs*61 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- FAM71F2 | c.495A>T p.Q165H | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM78B | c.757C>G p.P253A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- FANCE | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FBH1 | c.2393G>T p.R798M (on ENST00000362091 / NM_178150.3; = p.R849M on NM_032807.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBLN5 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 121/484 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBP1 | c.568-2del p.X190_splice | Splice Site (DEL) | VAF 48/317 reads (15%) | called by mutect2, varscan2
- FBXL5 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.564); called by muse, varscan2
- FBXL7 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 28/975 reads (3%) | called by muse, mutect2
- FFAR2 | c.550T>C p.C184R | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FHDC1 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- FHOD1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FIGNL1 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- FIGNL2 | c.1797del p.Q600Sfs*90 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- FJX1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FOXF2 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- FOXH1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXI1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 105/553 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FTCD | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- GALK2 | c.505-1G>T p.X169_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- GAR1 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GBA2 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GJD2 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- GLIS2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 94/497 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GPATCH8 | c.3410dup p.S1138Ifs*5 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- GPR179 | c.2692del p.A898Pfs*72 (on ENST00000621958; = p.A897Pfs*72 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 29/158 reads (18%) | called by mutect2, pindel, varscan2
- GPR6 | c.90dup p.P31Afs*21 | Frame Shift Ins (INS) | VAF 22/107 reads (21%) | called by mutect2, pindel, varscan2
- GRID2IP | c.2651A>G p.E884G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GRINA | c.333del p.N112Tfs*56 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by mutect2, varscan2
- GSAP | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GSDME | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GSE1 | c.3278del p.P1093Qfs*45 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- GSE1 | c.3479G>T p.S1160I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GXYLT1 | c.1225dup p.T409Nfs*70 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel
- GXYLT1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- H1-0 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H6PD | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HCFC2 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HMCN1 | c.6952G>A p.G2318S | Missense Mutation (SNP) | VAF 73/525 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPD | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- HNRNPL | c.1100del p.P367Hfs*28 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- HOATZ | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HPS6 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 108/527 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- HS6ST3 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HYAL1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ICE1 | c.1229dup p.N410Kfs*2 | Frame Shift Ins (INS) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- IGF2R | c.5416C>A p.L1806M | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IGFALS | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- IGHV3-16 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 92/430 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IGLON5 | c.735dup p.A246Rfs*9 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | called by mutect2, varscan2
- IL2RG | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INPP1 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- INPP5E | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRGQ | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- IRX3 | c.706del p.E236Rfs*24 | Frame Shift Del (DEL) | VAF 37/169 reads (22%) | called by mutect2, pindel, varscan2
- ITFG2 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ITGA2 | c.3144+1G>A p.X1048_splice | Splice Site (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- ITGAL | c.1127del p.G376Afs*5 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- ITGAX | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ITPR2 | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- KBTBD6 | c.1913G>A p.S638N | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- KCNA3 | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNA4 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH1 | c.1250G>A p.S417N (on ENST00000271751 / NM_172362.3; = p.S390N on NM_002238.4) | Missense Mutation (SNP) | VAF 347/885 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, varscan2
- KCNMA1 | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KDM1A | c.2489T>G p.L830W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM2B | c.3592C>A p.P1198T | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIF1B | c.3857T>G p.L1286R (on ENST00000377086 / NM_001365952.1; = p.L1240R on NM_015074.3) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21B | c.4736C>T p.P1579L (on ENST00000422435 / NM_001252100.2; = p.P1566L on NM_017596.4) | Missense Mutation (SNP) | VAF 96/785 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR2DL3 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- KPNA3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); called by muse, varscan2
- KRT1 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KRT28 | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LAMB1 | c.1086_1087del p.C362* | Nonsense Mutation (DEL) | VAF 10/78 reads (13%) | called by pindel, varscan2
- LBP | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LHCGR | c.1204T>C p.S402P | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMS2 | c.12-2A>G p.X4_splice (on ENST00000355119 / NM_001161403.3; = p.X28_splice on NM_017980.4) | Splice Site (SNP) | VAF 34/120 reads (28%) | called by muse, varscan2
- LINGO3 | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LIPE | c.3222del p.R1075Dfs*101 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- LRP1B | c.7969T>G p.W2657G | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC8C | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 86/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTB4R | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAGEB10 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGI1 | c.1583dup p.L528Ffs*24 | Frame Shift Ins (INS) | VAF 40/289 reads (14%) | called by mutect2, pindel, varscan2
- MAMDC4 | c.2073A>G p.Q691= (on ENST00000445819; = p.Q612= on NM_206920.3) | Splice Region (SNP) | VAF 55/242 reads (23%) | called by muse, mutect2, varscan2
- MANEA | c.655-1G>T p.X219_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.2620C>T p.Q874* (on ENST00000456763 / NM_001128608.2; = p.Q868* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 61/345 reads (18%) | called by muse, mutect2, varscan2
- MAST2 | c.2750_2753del p.E917Vfs*7 | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- MAST2 | c.5290del p.L1764Sfs*32 | Frame Shift Del (DEL) | VAF 26/176 reads (15%) | called by mutect2, pindel, varscan2
- MAU2 | c.339_341del p.L113_S114delinsF | In Frame Del (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel, varscan2
- MBD6 | c.2820+2T>C p.X940_splice | Splice Site (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- MCMBP | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEIG1 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MEPCE | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MESP2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- METTL8 | c.549dup p.G184Rfs*11 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- MEX3C | c.1789A>G p.S597G | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MMADHC | c.702dup p.G235Wfs*10 | Frame Shift Ins (INS) | VAF 20/136 reads (15%) | called by mutect2, pindel, varscan2
- MMP11 | c.524del p.G175Afs*58 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- MNT | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MOB2 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MON1B | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2118del p.D707Tfs*7 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- MPP7 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.27A>G p.I9M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MSH6 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 21/237 reads (9%) | called by muse, mutect2
- MTTP | c.104del p.K35Sfs*21 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- MUC16 | c.809del p.P270Lfs*9 | Frame Shift Del (DEL) | VAF 49/254 reads (19%) | called by mutect2, pindel, varscan2
- MUC2 | c.2191del p.D731Tfs*24 | Frame Shift Del (DEL) | VAF 65/298 reads (22%) | called by mutect2, pindel, varscan2
- MUC5B | c.10457_10458del p.E3486Afs*29 | Frame Shift Del (DEL) | VAF 83/774 reads (11%) | called by pindel, varscan2
- MYBBP1A | c.3152A>C p.E1051A | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MYBL1 | c.2120del p.K707Rfs*23 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.9470dup p.K3158Efs*4 (on ENST00000357337; = p.K3196Efs*4 on NM_015057.5) | Frame Shift Ins (INS) | VAF 37/251 reads (15%) | called by mutect2, pindel, varscan2
- MYH15 | c.3019G>T p.A1007S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MYLK | c.3866G>A p.S1289N | Missense Mutation (SNP) | VAF 109/575 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYLK | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYO18B | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, varscan2
- MYOZ3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NALCN | c.3431G>T p.C1144F | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NBEAL2 | c.8137G>A p.V2713M | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NBEAL2 | c.8183C>T p.A2728V | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NBN | c.1967T>C p.L656S | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- NCAM2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP1 | c.2308C>A p.L770I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NCOA7 | c.209dup p.R71Efs*4 | Frame Shift Ins (INS) | VAF 27/152 reads (18%) | called by mutect2, varscan2
- NDUFAF1 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NECTIN3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NEDD4L | c.2194A>G p.I732V (on ENST00000400345 / NM_001144967.3; = p.I712V on NM_015277.6) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NEK1 | c.3718G>A p.A1240T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NEK9 | c.668G>C p.C223S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- NFASC | c.514G>A p.V172I (on ENST00000339876 / NM_001378329.1; = p.V166I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NHSL2 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- NIN | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- NIPBL | c.6155A>C p.E2052A | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRC5 | c.2809C>T p.H937Y | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- NLRP7 | c.2938del p.C980Afs*32 (on ENST00000340844 / NM_206828.3; = p.C1009Afs*32 on NM_139176.3) | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | called by mutect2, varscan2
- NRG1 | c.1571A>C p.E524A (on ENST00000405005 / NM_013964.5; = p.E529A on NM_013956.5) | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NRXN3 | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTN5 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUMA1 | c.5894T>C p.L1965P | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP43 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUTM2E | c.2636A>G p.*879Wext*38 | Nonstop Mutation (SNP) | VAF 55/253 reads (22%) | called by muse, mutect2, varscan2
- NXF3 | c.629T>C p.M210T | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NYNRIN | c.5444G>T p.R1815M | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- OBSCN | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OCEL1 | c.500C>A p.A167E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGFR | c.171+1G>A p.X57_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- OLIG2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ONECUT2 | c.1228+1G>T p.X410_splice | Splice Site (SNP) | VAF 41/175 reads (23%) | called by muse, mutect2, varscan2
- OPN4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR1D5 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 107/571 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- OR8D2 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, varscan2
- OS9 | c.550A>T p.N184Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OSBP | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OSBPL2 | c.122del p.N41Ifs*40 (on ENST00000313733 / NM_144498.4; = p.N29Ifs*40 on NM_014835.4) | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- OSBPL8 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2
- OTUD5 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- OVGP1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 71/367 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PACS2 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PADI6 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PANX3 | c.540-1G>T p.X180_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- PAX1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PC | c.276del p.V93Cfs*19 | Frame Shift Del (DEL) | VAF 98/546 reads (18%) | called by mutect2, varscan2
- PCDH1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PCDH10 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB10 | c.2059T>A p.L687M | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.104); called by muse, mutect2
- PCDHB9 | c.2053T>A p.L685M | Missense Mutation (SNP) | VAF 99/856 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.168); called by muse, varscan2
- PCDHGA12 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
694 further variants in this file (208 protein-altering or splice-affecting, 289 silent, 197 other) are not listed here.
